Somatic mutation profile of tumor specimen MP2PRT-PAPJCF-TMP1-A (aliquot MP2PRT-PAPJCF-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPJCF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,384 days).
Specimen MP2PRT-PAPJCF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28eddbfe-f543-4ae8-b97e-ec1b7a1de4ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPJCF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPJCF-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b2634fb-6e69-44f7-be63-145cf617ba7b

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT4 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 156/334 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56110735; called by muse, varscan2
- RYR2 | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 129/333 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs1438792084, COSV100771770; called by muse, mutect2, varscan2
- TFAP2D | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 113/281 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as rs373515669, COSV50419258; called by muse, varscan2
- IGHV1-69 | c.348_349insCCTCG p.R117Pfs*? | Frame Shift Ins (INS) | VAF 45/92 reads (49%) | called by pindel, varscan2
- INPP4A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 117/289 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SLA2 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 138/385 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARF1 | c.4554T>C p.Y1518= | Silent (SNP) | VAF 241/510 reads (47%) | called by muse, mutect2, varscan2
